Somatic mutation profile of tumor specimen TCGA-G3-A6UC-01A (aliquot TCGA-G3-A6UC-01A-21D-A33K-10) from TCGA case TCGA-G3-A6UC, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 65.1 years (23,793 days).
Specimen TCGA-G3-A6UC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15796e39-8446-441c-b5c2-23b44d83dd5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A6UC-10A (Blood Derived Normal), aliquot TCGA-G3-A6UC-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68a90fb1-2985-43f5-8e59-9584471a08fe

The open-access MAF lists 137 somatic variants for this specimen: 98 protein-altering or splice-affecting, 35 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 35, Nonsense Mutation 4, Splice Region 3, RNA 2, Frame Shift Del 2, Intron 2, In Frame Ins 1, Nonstop Mutation 1, Frame Shift Ins 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 65/146 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.7030G>A p.D2344N (on ENST00000272895 / NM_173076.3; = p.D2026N on NM_015657.3) | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.241); catalogued as rs373723120; called by muse, mutect2, varscan2
- ABCB5 | c.866T>A p.V289E | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV51704255; called by muse, mutect2, varscan2
- ADCY3 | c.290C>A p.A97D | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV53165018, COSV53166789; called by muse, mutect2, varscan2
- AOX1 | c.3583A>G p.I1195V | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs1219886702, COSV53495489; called by muse, mutect2, varscan2
- ASS1 | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0.023); catalogued as rs762279472, COSV61688589; called by muse, mutect2, varscan2
- ATF6B | c.1872G>A p.M624I | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV64351396; called by muse, mutect2, varscan2
- BLVRA | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV55512807; called by muse, mutect2, varscan2
- BRINP3 | c.1840C>A p.L614M | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV66515117; called by muse, mutect2, varscan2
- CAND1 | c.2403A>C p.K801N | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV73389546; called by muse, mutect2, varscan2
- CCDC184 | c.295C>A p.Q99K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV100343933, COSV57252437; called by muse, mutect2, varscan2
- CEP250 | c.920A>G p.K307R | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.367); catalogued as COSV61168527; called by muse, mutect2, varscan2
- CGNL1 | c.826C>T p.L276F | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55564287; called by muse, mutect2, varscan2
- CLSTN2 | c.2260T>G p.Y754D | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71718673; called by muse, mutect2, varscan2
- CNTN6 | c.14G>A p.W5* | Nonsense Mutation (SNP) | VAF 58/157 reads (37%) | catalogued as COSV63163964; called by muse, mutect2, varscan2
- COL11A1 | c.183C>G p.C61W | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62174966, COSV62196162; called by muse, mutect2, varscan2
- COL1A2 | c.81G>A p.E27= | Splice Region (SNP) | VAF 80/286 reads (28%) | catalogued as COSV51953960, COSV51955392; called by muse, mutect2, varscan2
- CUL9 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV52726008; called by muse, mutect2, varscan2
- DIDO1 | c.2573-2A>T p.X858_splice | Splice Site (SNP) | VAF 16/35 reads (46%) | catalogued as COSV56615466; called by muse, mutect2, varscan2
- DNAH1 | c.12700T>A p.S4234T | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56231404; called by muse, mutect2, varscan2
- FAM124A | c.951C>A p.S317R (on ENST00000322475 / NM_001242312.2; = p.S353R on NM_145019.4) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.162); catalogued as COSV54474655; called by muse, mutect2, varscan2
- FANCD2 | c.4028G>A p.G1343E | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55033944; called by muse, mutect2, varscan2
- FHOD3 | c.590C>A p.T197N | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs147225084, COSV57166299; called by muse, mutect2, varscan2
- FRAS1 | c.6556G>C p.D2186H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV53594050; called by muse, mutect2, varscan2
- GLDC | c.965T>A p.V322E | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58677058; called by muse, mutect2, varscan2
- GTF2B | c.534A>G p.K178= | Splice Region (SNP) | VAF 27/66 reads (41%) | catalogued as COSV65136703; called by muse, mutect2, varscan2
- H2BC21 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV58611391, COSV58612648; called by muse, mutect2, varscan2
- HDAC10 | c.291G>T p.P97= | Splice Region (SNP) | VAF 34/54 reads (63%) | catalogued as rs763302996, COSV53132217, COSV53134557; called by muse, mutect2, varscan2
- HTT | c.9427T>A p.*3143Rext*8 | Nonstop Mutation (SNP) | VAF 40/75 reads (53%) | catalogued as COSV61858302; called by muse, mutect2, varscan2
- IRS4 | c.2195A>G p.H732R | Missense Mutation (SNP) | VAF 75/82 reads (91%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as COSV64532854; called by muse, mutect2, varscan2
- ITM2A | c.419C>G p.A140G | Missense Mutation (SNP) | VAF 133/149 reads (89%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.926); catalogued as COSV64810667; called by muse, mutect2, varscan2
- KDM4C | c.2437T>G p.C813G | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101184690; called by muse, mutect2, varscan2
- KDM4C | c.2438G>A p.C813Y | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101184691; called by muse, mutect2, varscan2
- KLHL9 | c.380A>G p.E127G | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.542); catalogued as COSV62921245; called by muse, mutect2, varscan2
- KMT5B | c.299T>G p.M100R | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58564220; called by muse, mutect2, varscan2
- LAMA5 | c.7549A>G p.R2517G | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.535); catalogued as COSV53354290; called by muse, mutect2, varscan2
- LAMC1 | c.4672G>A p.V1558M | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV51133702; called by muse, mutect2, varscan2
- LCK | c.76C>G p.P26A | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV60738869; called by muse, mutect2, varscan2
- MAGEA6 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV61448730; called by muse, mutect2
- MAP6D1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.925); catalogued as COSV57700075; called by muse, mutect2, varscan2
- MAPK10 | c.290C>T p.T97M (on ENST00000359221 / NM_001351625.2; = p.T135M on NM_002753.5) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs138883015; called by muse, mutect2, varscan2
- MECOM | c.2498G>C p.G833A (on ENST00000468789 / NM_001105078.4; = p.G1021A on NM_004991.4) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as COSV52960707; called by muse, mutect2
- MORC2 | c.2829A>G p.I943M (on ENST00000397641 / NM_001303256.3; = p.I881M on NM_014941.3) | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV53196656; called by muse, mutect2, varscan2
- MYH1 | c.2478G>A p.M826I | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV56844633; called by muse, mutect2, varscan2
- NEK9 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1305927894, COSV53129610; called by muse, mutect2, varscan2
- OR6F1 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as COSV57467084, COSV57468179; called by muse, mutect2, varscan2
- OR9Q2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV61111488; called by muse, mutect2, varscan2
- PABPC5 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV100442228, COSV57039378; called by muse, mutect2, varscan2
- PBRM1 | c.3740C>T p.T1247I (on ENST00000296302 / NM_001366071.2; = p.T1222I on NM_018313.5) | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56263935; called by muse, mutect2, varscan2
- PDZK1 | c.419A>G p.K140R | Missense Mutation (SNP) | VAF 247/429 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782040972, COSV61091993; called by muse, mutect2, varscan2
- PDZRN4 | c.1361T>A p.L454* (on ENST00000402685 / NM_001164595.2; = p.L196* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 30/67 reads (45%) | catalogued as COSV54194031; called by muse, mutect2, varscan2
- PEX13 | c.199A>G p.S67G | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54369325; called by muse, mutect2, varscan2
- PHGDH | c.1176C>A p.N392K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65570451; called by muse, mutect2, varscan2
- PKP4 | c.2768G>A p.G923D | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV61578068; called by muse, mutect2, varscan2
- PLA2G4A | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV100820425; called by muse, mutect2, varscan2
- PLA2G4A | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs758024598, COSV100820426; called by muse, mutect2, varscan2
- PLCG1 | c.977T>C p.L326P | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54815969; called by muse, mutect2, varscan2
- PLPP1 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV53303757; called by muse, mutect2, varscan2
- PRICKLE1 | c.1561C>G p.L521V | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV58204691; called by muse, mutect2, varscan2
- PRKD2 | c.1865A>T p.K622I | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV52184898; called by muse, mutect2, varscan2
- PRMT9 | c.1755A>T p.L585F | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV59358752; called by muse, mutect2, varscan2
- PRSS16 | c.1316T>C p.V439A | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV57914990; called by muse, mutect2, varscan2
- PSMB7 | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as COSV52329503; called by muse, mutect2, varscan2
- QTRT2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV55559024; called by muse, mutect2, varscan2
- ROCK2 | c.2330A>T p.E777V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV59954032; called by muse, mutect2, varscan2
- SALL1 | c.2698A>G p.N900D | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV51754219; called by muse, mutect2, varscan2
- SENP7 | c.2348T>A p.F783Y | Missense Mutation (SNP) | VAF 111/281 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV58608844; called by muse, mutect2, varscan2
- SLC14A2 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54906961; called by muse, mutect2, varscan2
- SLFN13 | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as rs767814242, COSV53192471; called by muse, mutect2, varscan2
- SMAD3 | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs191612061, COSV59281069; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPI1 | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV57044144; called by muse, mutect2, varscan2
- TASOR | c.1638C>A p.S546R (on ENST00000355628 / NM_001365636.2; = p.S150R on NM_015224.3) | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as COSV62927021; called by muse, mutect2, varscan2
- TEP1 | c.271A>C p.M91L | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV52988994; called by muse, mutect2, varscan2
- TRA2A | c.667G>C p.G223R | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.974); catalogued as COSV51715976, COSV51716539; called by muse, mutect2, varscan2
- TTC13 | c.322T>G p.S108A | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV64167921; called by muse, mutect2, varscan2
- TTI2 | c.962T>A p.I321N | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV62452163; called by muse, mutect2, varscan2
- TTN | c.41598G>T p.K13866N (on ENST00000591111; = p.K6442N on NM_003319.4) | Missense Mutation (SNP) | VAF 36/74 reads (49%) | PolyPhen benign (0.167); catalogued as COSV59916238; called by muse, mutect2, varscan2
- TUBAL3 | c.229T>A p.L77M | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.465); catalogued as COSV66814015; called by muse, mutect2, varscan2
- TXNL1 | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as COSV54178494; called by muse, mutect2, varscan2
- USP54 | c.3815C>G p.S1272C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV60440265, COSV60441377; called by muse, mutect2, varscan2
- USP6 | c.3341A>G p.D1114G | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.026); catalogued as COSV51476598; called by muse, mutect2, varscan2
- WNT8B | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100648936, COSV59324698; called by muse, mutect2, varscan2
- ZBTB2 | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100287530, COSV57314121; called by muse, mutect2, varscan2
- ZBTB43 | c.935A>T p.D312V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV65094452; called by muse, mutect2, varscan2
- ZBTB5 | c.1744C>A p.P582T | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57039011; called by muse, mutect2, varscan2
- ZDHHC23 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV57628852; called by muse, mutect2, varscan2
- ZFC3H1 | c.4538T>G p.V1513G | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV66430644; called by muse, mutect2, varscan2
- ZNF318 | c.5488A>C p.M1830L | Missense Mutation (SNP) | VAF 57/255 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV58930033, COSV58930598; called by muse, mutect2, varscan2
- ZNF331 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53475215; called by muse, mutect2, varscan2
- ZNF543 | c.299A>G p.E100G | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV58626573; called by muse, mutect2, varscan2
- ZNF7 | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV57382810; called by muse, mutect2, varscan2
- ZSCAN1 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.05); PolyPhen benign (0.425); catalogued as COSV56602371; called by muse, mutect2, varscan2
- ZUP1 | c.1168A>T p.I390F | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63943994; called by muse, mutect2, varscan2
- FAM83D | c.1587_1596del p.K529Nfs*47 | Frame Shift Del (DEL) | VAF 27/92 reads (29%) | called by mutect2, pindel, varscan2
- PIGW | c.1076_1087del p.V359_E362del | In Frame Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- SP3 | c.682del p.I228Yfs*25 | Frame Shift Del (DEL) | VAF 29/67 reads (43%) | called by mutect2, pindel, varscan2
- UBXN7 | c.43_45dup p.G15dup | In Frame Ins (INS) | VAF 46/131 reads (35%) | called by pindel, varscan2
- ZDHHC20 | c.509dup p.F171Lfs*30 | Frame Shift Ins (INS) | VAF 158/424 reads (37%) | called by mutect2, pindel, varscan2
- ALDH7A1 | c.888A>G p.E296= | Silent (SNP) | VAF 163/470 reads (35%) | catalogued as COSV68628694; called by muse, mutect2, varscan2
- ANKRD55 | c.241T>C p.L81= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as COSV61944656; called by muse, mutect2, varscan2
- ATP8A2 | c.2316G>T p.A772= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs757284272, COSV54961024, COSV99680579; called by muse, mutect2
- CCDC184 | c.294C>A p.R98= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100343931; called by muse, mutect2, varscan2
- CCDC39 | c.1749T>A p.L583= | Silent (SNP) | VAF 41/99 reads (41%) | catalogued as COSV56479592; called by muse, mutect2, varscan2
- CCDC74A | c.933G>A p.E311= | Silent (SNP) | VAF 33/199 reads (17%) | catalogued as COSV54605556; called by muse, mutect2, varscan2
- CCDC74B | c.933G>A p.E311= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV60101152; called by muse, mutect2, varscan2
- CNGA3 | c.333C>A p.S111= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV55622772; called by muse, mutect2, varscan2
- DCPS | c.462G>A p.T154= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs776003149, COSV55010162; called by muse, mutect2, varscan2
- ESS2 | c.987A>G p.E329= | Silent (SNP) | VAF 50/118 reads (42%) | catalogued as COSV52816298; called by muse, mutect2, varscan2
- EXPH5 | c.4635G>A p.Q1545= | Silent (SNP) | VAF 41/85 reads (48%) | catalogued as COSV56199510; called by muse, mutect2, varscan2
- FAT3 | c.4857C>T p.V1619= | Silent (SNP) | VAF 70/162 reads (43%) | catalogued as COSV53083072, COSV99970553; called by muse, mutect2, varscan2
- FLG | c.4767C>A p.R1589= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as rs368218057; called by muse, mutect2, varscan2
- FLRT2 | c.1281C>A p.L427= | Silent (SNP) | VAF 54/131 reads (41%) | catalogued as COSV58137321; called by muse, mutect2, varscan2
- LCTL | c.819C>G p.P273= | Silent (SNP) | VAF 10/204 reads (5%) | catalogued as COSV58421621, COSV58423132; called by muse, mutect2
- MYBL2 | c.1587C>T p.Y529= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs768925904, COSV53827921; called by muse, mutect2, varscan2
- MYH1 | c.5166C>G p.T1722= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV56844626; called by muse, mutect2, varscan2
- NOTCH4 | c.4680G>T p.A1560= | Silent (SNP) | VAF 62/163 reads (38%) | catalogued as COSV66679226; called by muse, mutect2, varscan2
- NSUN3 | c.135A>G p.T45= | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as COSV58934218; called by muse, mutect2, varscan2
- NUAK2 | c.1173G>A p.T391= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as rs149020592; called by muse, mutect2, varscan2
- P2RX2 | c.846G>A p.K282= (on ENST00000343948 / NM_170683.4; = p.K210= on NM_012226.5) | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV57675287; called by muse, mutect2, varscan2
- PANK2 | c.1338G>A p.V446= (on ENST00000316562 / NM_153638.3; = p.V155= on NM_024960.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as COSV57253270; called by muse, mutect2, varscan2
- PLXNA4 | c.5139C>A p.I1713= | Silent (SNP) | VAF 41/181 reads (23%) | catalogued as COSV58108940; called by muse, mutect2, varscan2
- PPP1R3A | c.585T>A p.V195= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as COSV52877826; called by muse, mutect2, varscan2
- PRDM8 | c.666C>A p.G222= | Silent (SNP) | VAF 64/144 reads (44%) | catalogued as COSV60202746; called by muse, varscan2
- PSG3 | c.852C>A p.P284= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV100548594, COSV59502860; called by muse, mutect2, varscan2
- SIRPB1 | c.1035C>G p.A345= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as COSV53537740; called by muse, mutect2, varscan2
- SLC1A1 | c.138T>C p.T46= | Silent (SNP) | VAF 49/196 reads (25%) | catalogued as rs1347276818, COSV52050226; called by muse, mutect2, varscan2
- SOCS7 | c.420C>T p.V140= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs918445588; called by muse, mutect2, varscan2
- SP140 | c.24G>A p.G8= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as rs752828812, COSV59447044, COSV59454655; called by muse, mutect2, varscan2
- SSMEM1 | c.633G>A p.A211= | Silent (SNP) | VAF 97/348 reads (28%) | catalogued as rs374890168, COSV52833115; called by muse, varscan2
- UBE4A | c.1335A>G p.L445= (on ENST00000252108 / NM_001204077.2; = p.L452= on NM_004788.4) | Silent (SNP) | VAF 49/104 reads (47%) | catalogued as COSV52802926; called by muse, mutect2, varscan2
- YLPM1 | c.318G>T p.P106= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV53107334; called by muse, mutect2, varscan2
- ZBTB2 | c.480G>A p.R160= | Silent (SNP) | VAF 42/50 reads (84%) | catalogued as rs757054645, COSV100287529; called by muse, mutect2, varscan2
- ZGPAT | c.117G>A p.L39= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV60831359; called by muse, mutect2, varscan2
- C8orf86 | n.520A>G | RNA (SNP) | VAF 29/42 reads (69%) | catalogued as COSV63935151; called by muse, mutect2, varscan2
- FMN1 | c.2044-2490T>C | Intron (SNP) | VAF 41/157 reads (26%) | catalogued as COSV57918819; called by muse, mutect2, varscan2
- FMN1 | c.2044-2709T>A | Intron (SNP) | VAF 38/121 reads (31%) | catalogued as rs184741064, COSV57918832; called by muse, mutect2, varscan2
- OR2W5 | n.1128del | RNA (DEL) | VAF 87/306 reads (28%) | called by mutect2, pindel, varscan2
